Surgical pathology report (de-identified scan), TCGA case TCGA-21-1079, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1079-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

- A: LEVEL 9 NODE
- B: LEVEL 10 NODES
- C: LEFT LUNG
- D: LEVEL 5 LYMPH NODES
- E: LEVEL 7 LYMPH NODES

Gross Description:

GROSS DESCRIPTION: Received in five parts.

A) Labeled #1, "level IX lymph node". Received fresh for frozen section evaluation is a 0.8 x 0.6 x 0.3cm gray-black lymph node. Specimen is submitted in toto for frozen section evaluation and the frozen itself is submitted labeled AFS.

FROZEN SECTION DIAGNOSIS: AFS - NO TUMOR SEEN.

B) Labeled #2, "level X nodes". Received fresh is a 0.6 x 0.4 x 0.3cm gray-black rubbery firm lymph node which is submitted in toto labeled B.

C) Labeled #3, "left lung". Received fresh for frozen section evaluation is a 420 gram, 20.5 x 14.5 x 4.5cm left pneumonectomy specimen. It is covered by a pink-red pleura. There is a 2.5cm of attached bronchus and the bronchial margin is submitted for frozen section evaluation. The frozen section residue is submitted labeled CFS. In the anterior segment of the upper lobe there is a 4.5 x 3.5 x 2.0cm firm mass which on sectioning reveal light to gray-tan firm cut surfaces with focal friable, hemorrhagic areas. The mass surrounds the hilar area and grossly appears to extend to the overlying pleura. The remaining lung parenchyma is pink to red-brown and spongy. There are several palpable hilar lymph nodes, 0.4 to 1.0cm in greatest dimension. The cut surfaces of each are brown-black and anthracotic stained. Representative sections are submitted as follows: C1 -vascular margin, C2 thru C5 - tumor with overlying inked pleura, C6 thru C7 -representative tumor sections, C8 - random lung sections, C9 thru C10 -hilar lymph nodes.

FROZEN SECTION DIAGNOSIS: CFS - NEGATIVE BRONCHIAL MARGIN.

D) Labeled #4, "level V lymph node". Received fresh are three brown-black anthracotic stained lymph nodes, 0.4 to 1.2cm in greatest dimension. They are submitted in toto labeled D.

E) Labeled #5, "level VII lymph node". Received fresh is a 2.0 x 1.0 x 0.6cm yellow-tan lobulated fragment of adipose tissue which contains several red-black palpable lymph

[page 2 of 2]
nodes, 0.8 to 1.8cm in greatest dimension. Representative sections of each lymph node is submitted labeled E.

Final Diagnosis:

DIAGNOSIS:

A) LEVEL 9 NODE:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

B) LEVEL 10 NODE:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

C) LEFT LUNG:

- GRADE II-III SQUAMOUS CARCINOMA OF THE LUNG INVOLVING THE PLEURA AND

FOCALLY TO THE INKED PLEURAL MARGIN (SLIDE C3).

- NEGATIVE VASCULAR AND BRONCHIAL MARGINS OF RESECTION.

- SIX LYMPH NODES, ALL NEGATIVE FOR TUMOR (0/6).

D) LEVEL V LYMPH NODES:

- THREE LYMPH NODES, ALL NEGATIVE FOR TUMOR (0/3).

E) LEVEL VII LYMPH NODE:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

Source: NCI Genomic Data Commons file 98453f86-d056-4733-b2e4-54ccc128008e (TCGA-21-1079.DDCBA444-A2BD-48CC-A035-553126BCA0C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).